Somatic mutation profile of tumor specimen MP2PRT-PASTRA-TMP1-A (aliquot MP2PRT-PASTRA-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASTRA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,105 days).
Specimen MP2PRT-PASTRA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8dd3d0ec-b9c6-4d6e-b14e-5240f84ff227.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASTRA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASTRA-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0fef74c-5255-47b5-b5b7-37b2d582f0db

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 39/226 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRL2 | c.3844G>A p.E1282K (on ENST00000370717 / NM_001366005.1; = p.E1226K on NM_012302.4) | Missense Mutation (SNP) | VAF 90/302 reads (30%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.015); catalogued as rs199665935; called by muse, mutect2, varscan2
- AREG | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 32/176 reads (18%) | catalogued as rs1283640826; called by muse, mutect2, varscan2
- CACNA1H | c.4819C>T p.R1607C | Missense Mutation (SNP) | VAF 84/367 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1315448028; called by muse, varscan2
- CUL7 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54818891; called by muse, mutect2, varscan2
- FAM47C | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 123/751 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs1415620320, COSV63724383; called by muse, mutect2, varscan2
- MED21 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV51460855; called by muse, mutect2
- MUC5B | c.2332G>A p.G778S | Missense Mutation (SNP) | VAF 120/388 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.039); catalogued as rs1189312281; called by muse, mutect2
- MYO5B | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 78/438 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201920924, COSV53216168, COSV99545631; called by muse, mutect2, varscan2
- NOD1 | c.2763G>C p.Q921H | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs555869187; called by muse, mutect2, varscan2
- PIP4K2C | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 86/287 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757397412, COSV61605759; called by muse, mutect2, varscan2
- RSPO3 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 92/322 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs763043841, COSV104415935; called by muse, mutect2
- STARD9 | c.14087C>T p.S4696F | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1352126535; called by muse, mutect2, varscan2
- TMEM178A | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56143288; called by muse, mutect2
- YLPM1 | c.3643C>T p.R1215* | Nonsense Mutation (SNP) | VAF 46/293 reads (16%) | catalogued as rs1462144569; called by muse, mutect2, varscan2
- ARHGAP18 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 12/376 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DNAH8 | c.1995G>C p.M665I | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.085); called by muse, mutect2
- FAT2 | c.11498G>A p.C3833Y | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRG1 | c.817T>G p.F273V | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- NBPF12 | c.1930C>G p.Q644E | Missense Mutation (SNP) | VAF 13/299 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2
- STX10 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACOX3 | c.312C>T p.P104= | Silent (SNP) | VAF 161/333 reads (48%) | catalogued as rs754191819, COSV100712030, COSV62713695; called by muse, mutect2, varscan2
- ADAMTS3 | c.750C>T p.H250= | Silent (SNP) | VAF 95/398 reads (24%) | catalogued as rs142264188; called by muse, mutect2, varscan2
- DOK5 | c.669C>A p.V223= | Silent (SNP) | VAF 81/368 reads (22%) | catalogued as rs751001820; called by muse, mutect2, varscan2
- EFCAB6 | c.2751G>A p.S917= | Silent (SNP) | VAF 77/291 reads (26%) | catalogued as rs1396579305, COSV53068467; called by muse, mutect2, varscan2
- LRRC43 | c.118C>T p.L40= | Silent (SNP) | VAF 32/543 reads (6%) | catalogued as rs1402463045; called by muse, mutect2
- SHANK1 | c.3873C>T p.G1291= | Silent (SNP) | VAF 115/513 reads (22%) | called by muse, mutect2, varscan2
- CLCN3 | c.-341_-340insTCCCAGGCCT | 5'UTR (INS) | VAF 30/219 reads (14%) | called by mutect2, pindel, varscan2
